Somatic mutation profile of tumor specimen 0DRY7Y from CCDI case PBCHCB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 16.3 years (5,954 days).
Specimen 0DRY7Y: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8c43bc22-e4a0-4fd6-b0a9-e82d2a215d06.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRY89 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8eb53636-5e62-4a70-9482-1154d3e7d5b0

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Silent 1, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OOEP | c.286G>A p.V96I | Missense Mutation (SNP) | VAF 204/639 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0.018); catalogued as rs983499644, COSV64859101; called by muse, mutect2, varscan2
- HEXIM1 | c.305_325del p.D102_E108del | In Frame Del (DEL) | VAF 69/320 reads (22%) | called by mutect2, varscan2
- PIP4P1 | c.45C>G p.I15M | Missense Mutation (SNP) | VAF 66/286 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- ZNF879 | c.16C>T p.L6= | Silent (SNP) | VAF 137/467 reads (29%) | called by muse, mutect2, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 8/195 reads (4%) | called by muse, mutect2
